Somatic mutation profile of tumor specimen TCGA-ND-A4WC-01A (aliquot TCGA-ND-A4WC-01A-21D-A28R-08) from TCGA case TCGA-ND-A4WC, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage IB; Age at diagnosis: 83.3 years (30,434 days).
Specimen TCGA-ND-A4WC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47513b72-f984-4ae1-8003-c2e63e8a1654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ND-A4WC-10A (Blood Derived Normal), aliquot TCGA-ND-A4WC-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48a4e0a8-d3cc-4b95-bd23-014a50c757e3

The open-access MAF lists 4,324 somatic variants for this specimen: 3,478 protein-altering or splice-affecting, 752 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,978, Silent 752, Nonsense Mutation 408, Splice Site 46, Intron 44, RNA 22, Splice Region 21, Frame Shift Ins 14, 3'UTR 12, Nonstop Mutation 8, 3'Flank 6, 5'Flank 6.

Variants (750 of 4,324; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs137852516, CM021282, COSV52920162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.6610C>T p.R2204* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as rs752654519, COSV57326468, COSV99965912; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.4852C>T p.R1618* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as rs762083530, CM983653, COSV53726137; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEP83 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as rs1207804224, COSV51574274; ClinVar: pathogenic; called by muse, mutect2
- CFTR | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs397508296, CM920165, COSV50040595, COSV99140566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNGB1 | c.2185C>T p.R729* | Nonsense Mutation (SNP) | VAF 41/111 reads (37%) | catalogued as rs1352458826, COSV51906385; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CNGB3 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | catalogued as rs267606739, CM001967, COSV60697817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 33/84 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- DMD | c.4618G>T p.E1540* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as rs1557320151, CM098412, COSV63744696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 59/150 reads (39%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- HUWE1 | c.12559C>T p.R4187C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121918527, CM081661, COSV99470874; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAFAH1B1 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs121434487, CM004136; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, varscan2
- PKHD1 | c.10444C>T p.R3482C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs148617572, CM032336; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.9719G>A p.R3240Q | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146649803, CM051180, CM051181, COSV61861681; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RLIM | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569309459, CM151028, COSV100222889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SERPINC1 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121909566, CM910059; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC25A13 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as rs758827458, CM090577, CM139590, COSV99673842; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- SLC7A7 | c.1465T>C p.S489P | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs386833810, CM022850; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs587782596, CM920672, COSV52689134, COSV53283559, COSV53738947; ClinVar: pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.4846C>T p.R1616* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as rs752429062, COSV62137304; ClinVar: likely pathogenic; called by muse, varscan2
- A1CF | c.237C>T p.I79= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as rs777129780; called by muse, varscan2
- A4GNT | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs570351376, COSV52628354; called by muse, mutect2, varscan2
- AADACL2 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs780021458, COSV62930020; called by muse, mutect2, varscan2
- ABCA12 | c.2647G>A p.D883N (on ENST00000272895 / NM_173076.3; = p.D565N on NM_015657.3) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.301); catalogued as rs200973428, COSV55980386, COSV99792611; called by muse, mutect2, varscan2
- ABCA12 | c.1312G>A p.E438K (on ENST00000272895 / NM_173076.3; = p.E120K on NM_015657.3) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs562998767, COSV55967677; called by muse, mutect2, varscan2
- ABCA5 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs1180912574, COSV101201128; called by muse, mutect2, varscan2
- ABCA8 | c.2959T>C p.F987L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs776033851; called by mutect2, varscan2
- ABCB1 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs199779996, COSV55951981; ClinVar: drug response; called by muse, mutect2, varscan2
- ABCB4 | c.2701G>A p.E901K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV55934686, COSV55936859; called by muse, mutect2, varscan2
- ABCB8 | c.1732G>A p.D578N (on ENST00000297504 / NM_001282291.2; = p.D561N on NM_007188.5) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as rs144722322; called by muse, mutect2, varscan2
- ABCC1 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766226776; called by muse, mutect2, varscan2
- ABCC10 | c.1957C>T p.L653= (on ENST00000372530 / NM_001198934.2; = p.L625= on NM_033450.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 15/55 reads (27%) | catalogued as rs750147259; called by muse, mutect2, varscan2
- ABCC12 | c.2784G>T p.E928D | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as COSV60915275; called by muse, mutect2, varscan2
- ABCC2 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.046); catalogued as rs1404271474; called by muse, mutect2, varscan2
- ABCC2 | c.4159T>C p.F1387L | Missense Mutation (SNP) | VAF 51/442 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564702291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC4 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs749961375, COSV65314575; called by mutect2, varscan2
- ABCC8 | c.2220C>T p.S740= | Splice Region (SNP) | VAF 14/40 reads (35%) | catalogued as COSV56849703; called by muse, mutect2, varscan2
- ABCG2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755591361, COSV52944852; called by muse, mutect2, varscan2
- AC104389.6 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 36/73 reads (49%) | catalogued as rs33963857, COSV100400543, COSV57963060; called by muse, mutect2, varscan2
- AC134980.2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770220391, COSV60907181; called by mutect2, varscan2
- ACE | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs753078890, COSV52017529; called by muse, varscan2
- ACSL1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as rs1369127114, COSV55662328; called by muse, mutect2, varscan2
- ACSL4 | c.331A>C p.N111H (on ENST00000340800 / NM_022977.2; = p.N70H on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61614282; called by muse, mutect2, varscan2
- ACSM2A | c.1312C>T p.R438* (on ENST00000219054; = p.R359* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 60/155 reads (39%) | catalogued as rs761163316, COSV99525297; called by muse, mutect2, varscan2
- ACSM2A | c.1656G>T p.K552N (on ENST00000219054; = p.K473N on NM_001308169.2) | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99525293; called by muse, mutect2, varscan2
- ACTB | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59316730; called by muse, mutect2, varscan2
- ACTL6A | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV66999088; called by muse, mutect2, varscan2
- ACTR8 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV51638659; called by muse, mutect2, varscan2
- ADAL | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101052500; called by muse, mutect2, varscan2
- ADAM18 | c.1639C>A p.L547I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs1240910186; called by muse, mutect2, varscan2
- ADAM21 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV99961053; called by muse, mutect2
- ADAM23 | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV52211747; called by muse, mutect2, varscan2
- ADAMTS14 | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750200846, COSV64600799; called by muse, mutect2, varscan2
- ADAMTS18 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867875220, COSV51406551; called by muse, mutect2, varscan2
- ADAMTS2 | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs574735794, COSV52368892; called by muse, mutect2, varscan2
- ADAMTS3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750800733, COSV54388911; called by muse, mutect2, varscan2
- ADAMTSL1 | c.677-1G>T p.X226_splice | Splice Site (SNP) | VAF 17/31 reads (55%) | catalogued as COSV52820085, COSV99442612; called by muse, mutect2, varscan2
- ADARB2 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs990745054, COSV67229363; called by muse, mutect2
- ADCY10 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as COSV63245163; called by muse, mutect2, varscan2
- ADCY7 | c.577A>C p.T193P | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV54267217; called by muse, mutect2, varscan2
- ADGRA3 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.535); catalogued as rs746516223, COSV51562557; called by muse, mutect2, varscan2
- ADGRD1 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.506); catalogued as rs755791900; called by muse, mutect2, varscan2
- ADGRE1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151096072, COSV51672989, COSV51674141; called by muse, mutect2, varscan2
- ADGRF1 | c.70-1G>A p.X24_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV64800724; called by muse, mutect2, varscan2
- ADGRG2 | c.872A>C p.N291T (on ENST00000379869 / NM_001079858.3; = p.N288T on NM_005756.4) | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV100491997; called by muse, mutect2, varscan2
- ADGRV1 | c.2466C>A p.F822L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67984094; called by muse, mutect2, varscan2
- ADGRV1 | c.13159C>T p.R4387C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs770485484, COSV67985727; called by mutect2, varscan2
- ADPRH | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779769148, COSV63694495; called by muse, mutect2, varscan2
- AFF1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as rs753451653, COSV100321078; called by muse, mutect2, varscan2
- AFF3 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs190577667, COSV57838935; called by muse, mutect2, varscan2
- AFF3 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as rs763782134, COSV100419865; called by muse, mutect2, varscan2
- AFTPH | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.911); catalogued as rs770856732; called by muse, mutect2, varscan2
- AGAP1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs373781245; called by muse, mutect2, varscan2
- AHCYL2 | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.364); catalogued as COSV61484809; called by muse, mutect2, varscan2
- AHNAK | c.13776G>T p.K4592N | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); catalogued as rs767436797; called by muse, mutect2, varscan2
- AIMP1 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 59/162 reads (36%) | catalogued as rs755959621, COSV63638898; called by muse, mutect2, varscan2
- AL592490.1 | c.2191C>A p.L731I | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.869); catalogued as COSV69426556; called by muse, mutect2, varscan2
- AL662899.2 | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as COSV65508068; called by muse, mutect2, varscan2
- ALAS2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM114505, COSV58188594, COSV58188642; called by muse, mutect2, varscan2
- ALB | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV55740248; called by muse, mutect2, varscan2
- ALDH16A1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 26/73 reads (36%) | catalogued as rs534259783; called by muse, mutect2, varscan2
- ALDH8A1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs749557929; called by muse, mutect2, varscan2
- ALG10B | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375350214, COSV58142173; called by muse, mutect2, varscan2
- ALG13 | c.2483C>A p.S828Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV52635852; called by muse, mutect2, varscan2
- ALLC | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as rs1280789169; called by muse, mutect2, varscan2
- ALMS1 | c.5991G>T p.K1997N | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV100043203; called by muse, mutect2, varscan2
- ALOX5 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1047630934, COSV65550945; called by muse, mutect2, varscan2
- ALPK1 | c.2049C>A p.F683L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1190451372, COSV51586602; called by muse, mutect2, varscan2
- AMER3 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | catalogued as rs781541050, COSV100365992; called by muse, mutect2, varscan2
- AMPH | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV57731962, COSV57759788; called by muse, mutect2, varscan2
- ANAPC1 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs748283556; called by muse, mutect2, varscan2
- ANK1 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV55874619, COSV99702878; called by muse, mutect2, varscan2
- ANK2 | c.6082C>T p.R2028W | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs1411026310, COSV52150851; called by muse, mutect2, varscan2
- ANKAR | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV55610757; called by muse, mutect2, varscan2
- ANKDD1A | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760927682; called by muse, mutect2, varscan2
- ANKRD13C | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs1461634372, COSV52030719; called by muse, mutect2, varscan2
- ANKRD50 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs368187440; called by muse, mutect2, varscan2
- ANKS1B | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs377245260; called by muse, mutect2, varscan2
- ANP32A | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as rs771143708, COSV51189824; called by muse, mutect2, varscan2
- ANXA13 | c.717C>T p.L239= | Splice Region (SNP) | VAF 24/64 reads (38%) | catalogued as rs367655009; called by muse, mutect2, varscan2
- APBA2 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.198); catalogued as rs144849809; called by muse, mutect2, varscan2
- APC | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as CM040672, COSV57347257; called by muse, mutect2, varscan2
- APC | c.4570A>G p.I1524V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1554085974, CD058156, CD1110397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.6899C>A p.S2300Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99969952; called by muse, mutect2, varscan2
- APEX1 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs367614890; called by muse, mutect2, varscan2
- APLNR | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs767481092, COSV57241337; called by muse, mutect2, varscan2
- APOB | c.12698C>T p.S4233L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs377125320, COSV51925242; called by muse, mutect2, varscan2
- APOB | c.9107C>A p.S3036Y | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51925687; called by muse, mutect2, varscan2
- APOL5 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV50766491, COSV50768685; called by muse, mutect2
- ARAP1 | c.1585G>A p.A529T (on ENST00000393609 / NM_001040118.2; = p.A284T on NM_015242.4) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs191461128; called by muse, mutect2, varscan2
- ARAP3 | c.3844A>G p.I1282V | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.552); catalogued as rs1449584524; called by muse, mutect2, varscan2
- ARHGAP11A | c.2128G>T p.D710Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55705886, COSV55706251; called by muse, mutect2, varscan2
- ARHGAP24 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs571519833, COSV67834201; called by muse, mutect2, varscan2
- ARHGAP26 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50827124; called by muse, mutect2, varscan2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGAP5 | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs927078439; called by muse, mutect2, varscan2
- ARHGAP6 | c.1728G>T p.Q576H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV100273747; called by muse, mutect2, varscan2
- ARHGEF11 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs935349970, COSV63810717; called by muse, mutect2, varscan2
- ARHGEF12 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1436675407, COSV63103826; called by muse, mutect2, varscan2
- ARHGEF5 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs578046612, COSV99282873; called by muse, mutect2, varscan2
- ARHGEF5 | c.4596G>T p.E1532D | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50214744; called by muse, mutect2, varscan2
- ARHGEF6 | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147323188; called by muse, mutect2, varscan2
- ARID1A | c.3667C>T p.R1223C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1227227387, COSV61371570; called by muse, mutect2, varscan2
- ARID1A | c.4086T>G p.Y1362* | Nonsense Mutation (SNP) | VAF 79/209 reads (38%) | catalogued as COSV61376941; called by muse, mutect2, varscan2
- ARID1B | c.6572C>T p.A2191V | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51679191; called by muse, mutect2, varscan2
- ARL4A | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs752253129; called by muse, mutect2, varscan2
- ARSD | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs776244005, COSV54203967; called by muse, mutect2, varscan2
- ARSL | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101140388; called by muse, mutect2, varscan2
- ASB16 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs573677324; called by muse, mutect2, varscan2
- ASF1A | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as COSV57647566, COSV57648220; called by muse, mutect2, varscan2
- ASPM | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756067585, COSV54125044; called by muse, mutect2, varscan2
- ASPM | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771828613, COSV54126357; called by muse, mutect2, varscan2
- ASPN | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs146516859; called by muse, mutect2, varscan2
- ASTN1 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.09); catalogued as rs773311364, COSV56068263; called by muse, mutect2, varscan2
- ASXL2 | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs866685548, COSV55459077, COSV55464030; called by muse, mutect2, varscan2
- ASXL2 | c.356A>G p.D119G | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as rs578025365; called by muse, mutect2, varscan2
- ATAD2 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1257928654, COSV54877532; called by muse, mutect2, varscan2
- ATCAY | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs201501328, COSV100009084; called by muse, mutect2, varscan2
- ATF6 | c.1778T>G p.I593S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100909219; called by muse, mutect2, varscan2
- ATG16L2 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs370896555; called by muse, mutect2, varscan2
- ATM | c.8854C>A p.L2952I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53737833, COSV53759315; called by muse, mutect2, varscan2
- ATP10A | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs146387652; called by muse, mutect2, varscan2
- ATP11B | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs1295948091, COSV60026923; called by muse, mutect2, varscan2
- ATP11C | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs754539347; called by muse, mutect2, varscan2
- ATP11C | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV100558626; called by muse, mutect2, varscan2
- ATP12A | c.2136G>T p.Q712H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54518553; called by muse, mutect2, varscan2
- ATP13A5 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs372618344; called by muse, mutect2, varscan2
- ATP1A2 | c.2656G>A p.D886N | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs757896422; called by muse, mutect2, varscan2
- ATP2B1 | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs746094247, COSV53807246; called by muse, mutect2, varscan2
- ATP2B3 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 99/333 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV54840734; called by muse, mutect2, varscan2
- ATP6V0D2 | c.562-2A>C p.X188_splice | Splice Site (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99571252; called by muse, mutect2, varscan2
- ATP6V1C1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV67777757; called by muse, mutect2, varscan2
- ATP8B1 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747906077; called by muse, mutect2, varscan2
- ATR | c.7219C>T p.R2407C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746049210, COSV63384106; called by muse, mutect2, varscan2
- ATR | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as COSV63388055; called by muse, varscan2
- ATRX | c.6614C>A p.T2205N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as COSV64870720; called by muse, mutect2, varscan2
- ATRX | c.4541G>A p.R1514Q | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV64874453; called by muse, mutect2
- ATXN3L | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as rs750682579, COSV101019305; called by muse, mutect2, varscan2
- ATXN3L | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV66075620; called by muse, mutect2, varscan2
- AUTS2 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100715453; called by muse, varscan2
- AVIL | c.1880A>G p.Q627R | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99142494; called by muse, mutect2, varscan2
- BAHD1 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs560381001; called by muse, mutect2, varscan2
- BBX | c.1615T>G p.S539A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.4); catalogued as COSV57895143; called by muse, mutect2, varscan2
- BCAS3 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs369466598; called by muse, mutect2, varscan2
- BCHE | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200998515, CM034212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL10 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs949558985, COSV104424132; called by muse, mutect2, varscan2
- BCORL1 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54391416; called by muse, mutect2, varscan2
- BCORL1 | c.3409A>G p.K1137E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV104373670; called by muse, mutect2
- BDH2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs1421023724, COSV56478221; called by muse, mutect2, varscan2
- BEGAIN | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1024781945; called by muse, mutect2
- BEND5 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1244423678, COSV65718609; called by muse, mutect2, varscan2
- BEST3 | c.1815C>A p.N605K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as rs898678774; called by muse, mutect2, varscan2
- BEX2 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 70/174 reads (40%) | catalogued as COSV101012839; called by muse, mutect2, varscan2
- BMP10 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54896526; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BMX | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1228626782; called by muse, mutect2, varscan2
- BNC1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766072426, COSV61757106, COSV61758012; called by muse, mutect2, varscan2
- BOD1L1 | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV50009652, COSV99238984; called by muse, varscan2
- BPI | c.434C>T p.S145L (on ENST00000262865; = p.S141L on NM_001725.3) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as rs201900727; called by muse, mutect2, varscan2
- BRCA2 | c.3268A>C p.M1090L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as CX1510466; called by muse, mutect2, varscan2
- BRCA2 | c.9538C>T p.L3180F | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200598289, CM1210132, COSV101200942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.10193A>G p.Q3398R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs374275215; called by muse, mutect2, varscan2
- BRCC3 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1557295542, COSV57461770; called by muse, mutect2, varscan2
- BRD8 | c.3445G>A p.D1149N | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1407571423; called by muse, mutect2, varscan2
- BRINP3 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as rs147790033, COSV66520603; called by muse, mutect2, varscan2
- BRS3 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101036581, COSV65710663; called by muse, mutect2, varscan2
- BRSK2 | c.268T>G p.Y90D | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.598); catalogued as COSV57541019; called by muse, mutect2, varscan2
- BRWD3 | c.4718G>T p.R1573I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV64746369; called by muse, mutect2, varscan2
- BRWD3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as rs1057521931, COSV64745244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD11 | c.1742G>A p.R581Q (on ENST00000280758 / NM_001018072.2; = p.R118Q on NM_001017523.2) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1485751402, COSV55024272; called by muse, mutect2, varscan2
- BTN3A2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV62687464; called by muse, mutect2, varscan2
- C10orf90 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs533281841, COSV52952500; called by muse, mutect2, varscan2
- C16orf70 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs758709116; called by muse, mutect2, varscan2
- C1orf54 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV64859404; called by muse, mutect2, varscan2
- C2CD3 | c.1070C>A p.S357Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as COSV58089406; called by muse, mutect2
- C2orf78 | c.1950C>A p.F650L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753364861, COSV68516704, COSV68519366; called by muse, mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C7orf50 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV62472864; called by muse, mutect2, varscan2
- C9orf131 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777411018, COSV100398040; called by muse, mutect2, varscan2
- C9orf43 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs746600411, COSV99928555; called by muse, mutect2, varscan2
- CA5B | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV59418028; called by muse, mutect2, varscan2
- CACNA1A | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as rs886042230, COSV64194925; called by muse, mutect2, varscan2
- CACNA1E | c.3945C>A p.F1315L | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV62431308; called by muse, mutect2, varscan2
- CACNA1E | c.4570G>T p.E1524* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV62385196; called by muse, mutect2, varscan2
- CACNA1F | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59903562; called by muse, mutect2, varscan2
- CACNA1H | c.6881C>A p.A2294D | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.07); catalogued as rs540026021; called by muse, varscan2
- CACNA2D1 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV100666986; called by muse, varscan2
- CACNA2D3 | c.871T>G p.F291V | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55556677; called by muse, mutect2
- CACNA2D3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as rs754529060, COSV55520924; called by muse, mutect2, varscan2
- CACNB4 | c.1433C>A p.S478Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52403560; called by muse, mutect2, varscan2
- CACNB4 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs747947877; called by muse, mutect2, varscan2
- CACNG3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as rs750272065, COSV50067133, COSV50080122; called by muse, mutect2, varscan2
- CACNG7 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55817780; called by muse, mutect2, varscan2
- CADPS | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs906307436, COSV51873515; called by muse, mutect2, varscan2
- CAMTA2 | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs184255864, COSV52779709; called by muse, mutect2, varscan2
- CAPN9 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV55231080; called by muse, mutect2, varscan2
- CAPN9 | c.809G>A p.R270K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55232544; called by muse, mutect2, varscan2
- CAPRIN1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | catalogued as COSV104419102; called by muse, mutect2, varscan2
- CASP7 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775867698, COSV61883310; called by muse, mutect2, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CASP8 | c.412-1G>T p.X138_splice (on ENST00000432109 / NM_033355.3; = p.X170_splice on NM_001228.4) | Splice Site (SNP) | VAF 42/118 reads (36%) | catalogued as COSV51845122, COSV51859458; called by muse, mutect2, varscan2
- CAST | c.393G>T p.K131N (on ENST00000341926; = p.K214N on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100352134; called by muse, varscan2
- CAST | c.2075C>T p.A692V (on ENST00000341926; = p.A775V on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as rs767408102; called by mutect2, varscan2
- CATSPERB | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.431); catalogued as rs150597625, COSV56430492; called by muse, mutect2, varscan2
- CATSPERB | c.757T>G p.F253V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs1215545289; called by muse, mutect2, varscan2
- CATSPERD | c.1509G>A p.S503= | Splice Region (SNP) | VAF 15/40 reads (38%) | catalogued as rs766707672, COSV58464186; called by muse, mutect2, varscan2
- CAV2 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV56063830, COSV99760773; called by muse, mutect2, varscan2
- CBX6 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53320267; called by muse, mutect2, varscan2
- CCBE1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as COSV71670852; called by muse, mutect2, varscan2
- CCDC102B | c.1496G>T p.R499I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100104763, COSV60155640; called by muse, varscan2
- CCDC114 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as rs754232429; called by muse, mutect2, varscan2
- CCDC15 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV100777059; called by muse, mutect2, varscan2
- CCDC15 | c.2788A>G p.N930D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV61080536, COSV61083540; called by muse, mutect2, varscan2
- CCDC30 | c.1542G>T p.E514D (on ENST00000340612; = p.E471D on NM_001080850.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV104412008; called by muse, mutect2, varscan2
- CCDC88A | c.2135C>A p.S712Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55060261; called by muse, mutect2, varscan2
- CCDC89 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.526); catalogued as COSV57034378; called by muse, mutect2, varscan2
- CCDC93 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 79/208 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs780144445, COSV60119225; called by muse, mutect2, varscan2
- CCND2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54223017; called by muse, mutect2, varscan2
- CCNI2 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749993881; called by muse, mutect2, varscan2
- CCNT1 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs768066318, COSV99980731; called by muse, mutect2, varscan2
- CCR3 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs756281359, COSV100656543, COSV62462751; called by muse, mutect2, varscan2
- CCR8 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs1210009524; called by muse, mutect2, varscan2
- CCT4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs1218940061; called by muse, mutect2
- CD163L1 | c.4138C>A p.L1380I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.696); catalogued as COSV100549642, COSV58024022; called by muse, mutect2, varscan2
- CD200R1 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as COSV55600116; called by muse, mutect2, varscan2
- CD2AP | c.968A>C p.N323T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63759339; called by muse, mutect2, varscan2
- CD48 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.448); catalogued as COSV63567059; called by muse, mutect2, varscan2
- CD84 | c.952G>A p.E318K (on ENST00000311224 / NM_001184879.2; = p.E301K on NM_003874.4) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs779139394, COSV60866779; called by muse, mutect2, varscan2
- CDADC1 | c.724T>A p.L242I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1460526547; called by muse, mutect2, varscan2
- CDC16 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV52958807; called by muse, mutect2, varscan2
- CDC27 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV50707129; called by mutect2, varscan2
- CDC5L | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs374722205; called by muse, mutect2, varscan2
- CDH17 | c.1593C>A p.F531L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV50327687, COSV50343867; called by muse, mutect2, varscan2
- CDH23 | c.1963G>A p.V655I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.841); catalogued as rs374805957, COSV54940166; ClinVar: uncertain significance; called by mutect2, varscan2
- CDH23 | c.5570A>G p.N1857S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.615); catalogued as rs768168909; called by muse, mutect2, varscan2
- CDK19 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV60448582; called by muse, mutect2, varscan2
- CDKL5 | c.2355G>T p.K785N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as COSV66110341; called by muse, mutect2, varscan2
- CDKN2A | c.128G>T p.S43I | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV58723457, COSV58726585; called by muse, mutect2, varscan2
- CDR1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs750462374, COSV65163903; called by muse, mutect2, varscan2
- CDRT1 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs372782740; called by mutect2, varscan2
- CENPF | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV65273518; called by muse, mutect2
- CENPJ | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV67883408; called by muse, mutect2, varscan2
- CEP104 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.665); catalogued as rs548824624; called by muse, mutect2, varscan2
- CEP135 | c.2764C>T p.R922* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as rs369943972; called by muse, mutect2, varscan2
- CEP152 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs776054120; called by muse, mutect2, varscan2
- CEP162 | c.3725C>A p.S1242Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs756224926, COSV57619607; called by muse, mutect2, varscan2
- CEP250 | c.5083C>T p.R1695* | Nonsense Mutation (SNP) | VAF 53/154 reads (34%) | catalogued as rs746831149, COSV61168070; called by muse, mutect2, varscan2
- CEP290 | c.5975G>T p.R1992I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV58352903; called by muse, mutect2, varscan2
- CEP55 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs146596670; called by muse, mutect2, varscan2
- CEP55 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs370361002, COSV65185463; called by muse, mutect2, varscan2
- CERS3 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs904261909, COSV52564617; called by muse, varscan2
- CERS3 | c.176T>G p.F59C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1291683832; called by muse, varscan2
- CERT1 | c.1350C>A p.F450L (on ENST00000405807 / NM_001130105.1; = p.F322L on NM_005713.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54665193; called by muse, mutect2, varscan2
- CETP | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs748890214, COSV52363450; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.738); catalogued as rs760491203, COSV100291914; called by muse, mutect2, varscan2
- CFAP43 | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs761189614, COSV53376518; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP47 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as rs762876322, COSV52881324, COSV52884138; called by muse, mutect2, varscan2
- CFAP58 | c.2439G>T p.E813D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV63836579; called by muse, mutect2, varscan2
- CHD1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV52343096; called by muse, mutect2, varscan2
- CHD4 | c.1244C>A p.S415* (on ENST00000357008 / NM_001363606.2; = p.S428* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 129/326 reads (40%) | catalogued as COSV58901126; called by muse, mutect2, varscan2
- CHD5 | c.3276G>T p.Q1092H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV52418873; called by muse, mutect2, varscan2
- CHL1 | c.865G>T p.E289* (on ENST00000397491 / NM_001253387.1; = p.E305* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99851727; called by muse, mutect2, varscan2
- CHODL | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100166933, COSV54731287; called by muse, mutect2, varscan2
- CHORDC1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100272155, COSV57706659; called by muse, mutect2, varscan2
- CHST11 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV57987306; called by muse, mutect2, varscan2
- CIAPIN1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1479202972, COSV67953549; called by muse, mutect2, varscan2
- CIBAR2 | c.538-1G>T p.X180_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV73320635; called by muse, mutect2, varscan2
- CIPC | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as rs373673890, COSV62377238; called by muse, mutect2, varscan2
- CIR1 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100564876; called by muse, mutect2
- CIT | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1433521956, COSV55861679; called by muse, mutect2, varscan2
- CLASP1 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV55313295; called by muse, mutect2, varscan2
- CLCA1 | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.104); catalogued as COSV52327573; called by muse, mutect2, varscan2
- CLCN7 | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs767015118; called by muse, mutect2, varscan2
- CLDN19 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.322); catalogued as rs571067526, COSV56418923; called by muse, mutect2, varscan2
- CLDN20 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs538851441, COSV65697889; called by muse, mutect2, varscan2
- CLDND1 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.336); catalogued as rs141592597; called by mutect2, varscan2
- CLEC14A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV60563223, COSV60563655; called by muse, mutect2, varscan2
- CLEC17A | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | catalogued as COSV60427863; called by muse, mutect2, varscan2
- CLEC4A | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs773649897, COSV57561538; called by muse, mutect2, varscan2
- CLEC5A | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV69397285; called by muse, mutect2, varscan2
- CLSPN | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 57/154 reads (37%) | catalogued as rs894279301, COSV52050423; called by muse, mutect2, varscan2
- CLSTN1 | c.487G>A p.V163M (on ENST00000377298 / NM_001009566.3; = p.V153M on NM_014944.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs749102307, COSV63649693; called by muse, mutect2, varscan2
- CLSTN2 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756136789, COSV71723435; called by muse, mutect2, varscan2
- CLSTN3 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs1431310043; called by muse, mutect2, varscan2
- CLTC | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.306); catalogued as rs756221208; called by mutect2, varscan2
- CLTCL1 | c.2966C>T p.S989L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781858778, COSV54227380; called by muse, mutect2, varscan2
- CMTM5 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs751840348; called by muse, mutect2, varscan2
- CMYA5 | c.3920C>A p.S1307Y | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV71404884; called by muse, mutect2, varscan2
- CMYA5 | c.11558C>A p.S3853Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs907830031, COSV69746273; called by muse, varscan2
- CNBD1 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs370736889, COSV72976790; called by muse, mutect2, varscan2
- CNDP1 | c.1207A>C p.S403R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62595555; called by muse, mutect2, varscan2
- CNGB3 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV60699177; called by muse, mutect2, varscan2
- CNNM1 | c.2176C>T p.L726= | Splice Region (SNP) | VAF 17/34 reads (50%) | catalogued as rs749240498, COSV63202163; called by muse, mutect2, varscan2
- CNR2 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs200710174; called by muse, mutect2, varscan2
- CNTD1 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100162034; called by muse, mutect2, varscan2
- CNTN5 | c.675G>T p.E225D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.225); catalogued as COSV54312324; called by muse, mutect2
- COBLL1 | c.2950A>G p.M984V (on ENST00000392717; = p.M946V on NM_014900.5) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1167730555; called by muse, mutect2, varscan2
- COBLL1 | c.2551G>T p.E851* (on ENST00000392717; = p.E813* on NM_014900.5) | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | catalogued as COSV52067027; called by muse, mutect2, varscan2
- COG7 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as rs754431741, COSV56150331; called by muse, mutect2, varscan2
- COL11A1 | c.200C>A p.S67Y | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100616852; called by muse, mutect2, varscan2
- COL13A1 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758070758, COSV62568724; called by muse, mutect2, varscan2
- COL19A1 | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100504701; called by muse, mutect2, varscan2
- COL1A2 | c.2476G>T p.G826C | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV51958790; called by muse, mutect2, varscan2
- COL22A1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141938188, COSV57333337; called by muse, mutect2, varscan2
- COL4A1 | c.2840A>C p.K947T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65425499; called by muse, mutect2, varscan2
- COL4A5 | c.3190G>A p.D1064N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs377337832, COSV60359339; called by muse, mutect2, varscan2
- COL4A5 | c.4595G>T p.R1532I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60356939; called by muse, mutect2, varscan2
- COL6A2 | c.2134G>A p.D712N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as rs375608173; called by muse, mutect2, varscan2
- COL6A5 | c.7504G>T p.D2502Y (on ENST00000312481; = p.D2498Y on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV99593495; called by muse, mutect2, varscan2
- COL6A6 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs762186019; called by muse, mutect2, varscan2
- COL9A1 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as rs147237457; called by muse, mutect2, varscan2
- COLEC10 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.1); catalogued as rs748322589, COSV60520630; called by muse, mutect2, varscan2
- COPA | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 82/223 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759516454, COSV54104101; called by muse, mutect2, varscan2
- COPB1 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1182148424, COSV51448599, COSV99999434; called by muse, mutect2, varscan2
- COPS7B | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs147144693; called by muse, mutect2, varscan2
- CPNE2 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 16/137 reads (12%) | catalogued as rs1404503670; called by muse, mutect2, varscan2
- CPO | c.776T>C p.M259T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs754142292; called by muse, mutect2, varscan2
- CPVL | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55305561; called by muse, mutect2, varscan2
- CRABP1 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55116434; called by muse, mutect2, varscan2
- CREBBP | c.4951G>A p.D1651N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1488071616; called by muse, mutect2
- CREBBP | c.4175G>A p.R1392Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52120158; called by muse, mutect2, varscan2
- CREBBP | c.3148G>T p.E1050* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as COSV52136246; called by muse, mutect2, varscan2
- CRHR1 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1262907240, COSV53286974; called by muse, mutect2
- CSMD2 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.382); catalogued as rs201989989; called by muse, mutect2, varscan2
- CSMD3 | c.10651C>T p.R3551C (on ENST00000297405 / NM_001363185.1; = p.R3382C on NM_052900.3) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747094531, COSV52118225, COSV99830646, COSV99853569; called by muse, mutect2, varscan2
- CTCF | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | catalogued as COSV50462504, COSV50463659; called by muse, mutect2, varscan2
- CTDSPL2 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52945446, COSV52947505; called by muse, mutect2, varscan2
- CTNNA2 | c.2591C>T p.S864L (on ENST00000402739 / NM_001282597.3; = p.S816L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448881716, COSV58151496; called by muse, mutect2, varscan2
- CTNNBL1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs535666882, COSV63747704; called by muse, mutect2, varscan2
- CTSV | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs771264161, COSV52344711; called by muse, mutect2, varscan2
- CTTNBP2 | c.2582T>G p.L861R | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1372701419; called by muse, mutect2, varscan2
- CUL4B | c.2086C>A p.H696N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV60684893; called by muse, mutect2, varscan2
- CUZD1 | c.1221G>T p.K407N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100158912; called by muse, mutect2, varscan2
- CWC22 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772183680, COSV55432111; called by muse, mutect2, varscan2
- CWC22 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs1042314398, COSV55426455; called by muse, varscan2
- CXorf38 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs771360730; called by muse, mutect2, varscan2
- CXorf58 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418453985, COSV64858469; called by muse, mutect2, varscan2
- CXorf66 | c.682T>C p.S228P | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs746647609; called by muse, mutect2, varscan2
- CYFIP1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.154); catalogued as rs778270959; called by muse, mutect2, varscan2
- CYFIP2 | c.2254C>T p.R752* (on ENST00000616178 / NM_001291722.2; = p.R727* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs1353891660, COSV59044652; called by muse, mutect2
- CYFIP2 | c.3508G>A p.E1170K (on ENST00000616178 / NM_001291722.2; = p.E1145K on NM_014376.4) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV59029690; called by muse, mutect2, varscan2
- CYP20A1 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201088277, COSV61909261, COSV61909939; called by muse, mutect2, varscan2
- CYP2A7 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1341010533; called by muse, mutect2, varscan2
- CYP39A1 | c.1108T>G p.F370V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763522323; called by muse, mutect2, varscan2
- CYP3A43 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV55935947; called by muse, mutect2, varscan2
- CYP4B1 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs139750942; called by muse, mutect2, varscan2
- CYP4F8 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV57854406; called by muse, mutect2, varscan2
- CYP4Z1 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.388); catalogued as rs577489518, COSV61964725, COSV61965251; called by muse, mutect2, varscan2
- CYP51A1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99069370; called by muse, mutect2, varscan2
- CYP7A1 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV56964211; called by muse, mutect2, varscan2
- CYRIA | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.12); catalogued as COSV100838602, COSV62867287; called by muse, mutect2, varscan2
- CYTL1 | c.198+1G>A p.X66_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as rs144723757; called by muse, mutect2, varscan2
- DAAM1 | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1166170856, COSV62834780; called by muse, mutect2, varscan2
- DAB2 | c.321G>T p.E107D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57918587; called by muse, varscan2
- DAZL | c.800G>T p.R267I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV51712796; called by muse, mutect2, varscan2
- DCAF16 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 56/150 reads (37%) | catalogued as rs772452250, COSV66384064; called by muse, mutect2, varscan2
- DCAF4L1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1226690767; called by muse, mutect2, varscan2
- DCAF6 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs543895185, COSV56584471; called by muse, mutect2, varscan2
- DCC | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs202005334, COSV59117267, COSV59123651; called by muse, mutect2, varscan2
- DCC | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs759718173, COSV100498675, COSV59118423; called by muse, mutect2, varscan2
- DCC | c.1685G>T p.R562I | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100500286, COSV59099654; called by muse, varscan2
- DCC | c.2754C>A p.F918L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59083474; called by muse, mutect2, varscan2
- DCLK2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs768915804; called by mutect2, varscan2
- DCT | c.423C>A p.F141L | Missense Mutation (SNP) | VAF 103/285 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100986292; called by muse, mutect2, varscan2
- DCTN4 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1431523172; called by muse, mutect2, varscan2
- DDI1 | c.1151T>A p.I384N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV56375993; called by muse, mutect2, varscan2
- DDR1 | c.663C>T p.G221= | Splice Region (SNP) | VAF 23/30 reads (77%) | catalogued as rs773211020, COSV61320414; called by muse, mutect2, varscan2
- DDX4 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.704); catalogued as rs765470784, COSV61754023; called by muse, mutect2, varscan2
- DDX55 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as rs1425619441, COSV99434378; called by muse, mutect2, varscan2
- DDX60 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs780985010, COSV67096011; called by muse, mutect2, varscan2
- DDX60L | c.4251G>T p.K1417N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs959745035, COSV99488751; called by muse, mutect2
- DEAF1 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs143376874; called by muse, mutect2, varscan2
- DEFB118 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as COSV99489216; called by muse, mutect2, varscan2
- DEFB126 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs376573096; called by muse, mutect2, varscan2
- DENND3 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs767108350, COSV52801668; called by mutect2, varscan2
- DENND3 | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52800541; called by muse, mutect2, varscan2
- DENND4A | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV71265462, COSV71265533; called by muse, mutect2, varscan2
- DEUP1 | c.564C>G p.Y188* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV53215894; called by muse, mutect2, varscan2
- DGCR8 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV61228534; called by muse, mutect2, varscan2
- DHX36 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs774980712; called by muse, mutect2, varscan2
- DHX57 | c.2638C>T p.R880* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as rs965943997, COSV99769657; called by muse, mutect2, varscan2
- DIAPH2 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs41300144, COSV61294487; called by muse, mutect2, varscan2
- DIAPH3 | c.3265C>T p.R1089W (on ENST00000400324 / NM_001042517.2; = p.R826W on NM_030932.3) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); catalogued as rs1156923369, COSV57369657; called by muse, mutect2, varscan2
- DISP1 | c.2517C>A p.F839L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52660969, COSV99450642; called by muse, mutect2, varscan2
- DLEC1 | c.4958G>A p.R1653Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs573428697, COSV100086058; called by muse, mutect2, varscan2
- DLG2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs150043290, COSV65834644; called by muse, mutect2, varscan2
- DLG5 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750819054, COSV64950317; called by muse, mutect2, varscan2
- DLX5 | c.566G>T p.R189I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56033201; called by muse, mutect2, varscan2
- DMBT1 | c.6293G>A p.G2098D (on ENST00000338354 / NM_001377530.1; = p.G1341D on NM_004406.3) | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57559790; called by muse, mutect2, varscan2
- DMXL1 | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV60711795; called by muse, mutect2, varscan2
- DMXL1 | c.8085C>A p.F2695L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV60718689; called by muse, mutect2, varscan2
- DNAH10 | c.5155G>T p.E1719* (on ENST00000409039; = p.E1658* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV104435644; called by muse, mutect2, varscan2
- DNAH17 | c.4445C>T p.A1482V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.154); catalogued as rs756103212, COSV67758109; called by muse, mutect2, varscan2
- DNAH3 | c.12286A>G p.T4096A | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs767118160; called by muse, mutect2, varscan2
- DNAH5 | c.4072G>A p.G1358S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs752638332; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs767655417, COSV54226869; called by muse, mutect2, varscan2
- DNAH7 | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | catalogued as rs376917562, COSV56765219; called by muse, mutect2, varscan2
- DNAH7 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100415037, COSV56760037; called by muse, mutect2, varscan2
- DNAH8 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs768782343; called by muse, mutect2, varscan2
- DNAH8 | c.3820G>T p.E1274* | Nonsense Mutation (SNP) | VAF 35/53 reads (66%) | catalogued as COSV59424995; called by muse, mutect2, varscan2
- DNAH8 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1345752116, COSV59441238; called by muse, mutect2, varscan2
- DNAJC10 | c.1749C>A p.F583L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51136742; called by muse, varscan2
- DNAJC10 | c.1799G>T p.R600I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51139123, COSV51147140; called by muse, varscan2
- DNAJC11 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs201917830; called by muse, mutect2, varscan2
- DNAJC13 | c.1515G>T p.K505N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.583); catalogued as COSV53448338; called by muse, mutect2, varscan2
- DNAJC13 | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367802425, COSV53456266; called by muse, mutect2, varscan2
- DNAJC27 | c.59T>C p.I20T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1302124368; called by muse, mutect2, varscan2
- DNALI1 | c.403C>T p.R135W (on ENST00000296218; = p.R113W on NM_003462.5) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs1319117020; called by muse, mutect2, varscan2
- DOCK11 | c.5969T>G p.F1990C | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52234716; called by muse, mutect2, varscan2
- DOCK4 | c.3631C>A p.L1211I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.611); catalogued as COSV101312830, COSV69854077; called by muse, mutect2, varscan2
- DOCK4 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1365271106, COSV70315040; called by muse, mutect2, varscan2
- DOCK7 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs375898065, COSV99223901; called by muse, mutect2, varscan2
- DOK5 | c.169C>A p.H57N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as COSV52817022; called by muse, mutect2, varscan2
- DOP1A | c.4448G>A p.R1483Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as rs762632774; called by muse, mutect2, varscan2
- DPF2 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52889184, COSV52889268; called by muse, mutect2, varscan2
- DPH3 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs777253135; called by muse, varscan2
- DPP10 | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV59679975; called by muse, mutect2, varscan2
- DPP10 | c.2213T>G p.L738* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV59671649, COSV59689867; called by muse, varscan2
- DPP6 | c.1400C>T p.S467L (on ENST00000377770 / NM_001364500.2; = p.S405L on NM_001936.5) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.327); catalogued as rs752633287; called by muse, varscan2
- DPY19L4 | c.1865C>A p.S622* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as rs547862125; called by muse, mutect2, varscan2
- DRD2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs201628227; called by muse, mutect2, varscan2
- DSC1 | c.2163G>T p.K721N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); catalogued as COSV57151051; called by muse, varscan2
- DSC3 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs779053546, COSV100844420; called by muse, mutect2, varscan2
- DSCAM | c.2586C>A p.F862L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV68027079; called by muse, mutect2, varscan2
- DSG4 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs369555342; called by muse, mutect2, varscan2
- DSG4 | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs757879343; called by muse, mutect2, varscan2
- DST | c.15554C>A p.S5185Y (on ENST00000361203 / NM_001374722.1; = p.S2773Y on NM_015548.5) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54996964; called by muse, mutect2, varscan2
- DST | c.8788T>G p.F2930V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs375948740; called by muse, mutect2, varscan2
- DTNA | c.1050C>A p.F350L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52021709; called by muse, varscan2
- DTX4 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.207); catalogued as rs542889400, COSV57095094; called by muse, mutect2, varscan2
- DUSP13 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as rs377547251; called by muse, mutect2, varscan2
- DUSP16 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781428998, COSV99963066; called by muse, mutect2, varscan2
- DVL1 | c.161A>G p.Q54R | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs1390408053; called by muse, mutect2, varscan2
- DYM | c.1916T>G p.F639C | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53979798; called by muse, mutect2, varscan2
- DYNLRB1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); catalogued as COSV55964864; called by muse, mutect2, varscan2
- DYRK2 | c.397C>T p.R133W (on ENST00000344096 / NM_006482.3; = p.R60W on NM_003583.4) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs773201871; called by muse, mutect2, varscan2
- DYSF | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs144599077, CM1514313, COSV50316514; called by muse, mutect2, varscan2
- EDAR | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558793513, COSV51503957; called by muse, mutect2, varscan2
- EEF1A1 | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs1379362761; called by muse, mutect2, varscan2
- EFCAB13 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs149684195; called by muse, mutect2, varscan2
- EFCAB13 | c.1106T>G p.F369C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV58953000; called by muse, mutect2, varscan2
- EFCAB5 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs767868545, COSV57926096; called by muse, mutect2, varscan2
- EFCAB5 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as rs201514253, COSV57931698; called by muse, mutect2, varscan2
- EFEMP1 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100816870; called by muse, mutect2, varscan2
- EGF | c.356C>A p.S119Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1431492601; called by muse, mutect2, varscan2
- EHMT1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58372893; called by muse, mutect2, varscan2
- EIF2AK2 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV51794782; called by muse, mutect2, varscan2
- EIF2D | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV104377116; called by muse, mutect2, varscan2
- EIF2S1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV56452035; called by muse, mutect2, varscan2
- EIF6 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs1443047408; called by muse, mutect2, varscan2
- ELOVL7 | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV70917912; called by muse, mutect2, varscan2
- ELSPBP1 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1568409110, COSV100353690; called by muse, mutect2, varscan2
- EMILIN2 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54421311, COSV99598607; called by muse, mutect2, varscan2
- ENGASE | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs750151671, COSV56138198; called by muse, mutect2, varscan2
- ENPP3 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV62954068, COSV62954093; called by muse, mutect2, varscan2
- EPG5 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1455631275, COSV56352125; called by muse, mutect2, varscan2
- EPHA3 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 34/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100341609, COSV60708592, COSV60729757; called by muse, mutect2, varscan2
- EPHA3 | c.2236G>T p.D746Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60729666; called by muse, mutect2, varscan2
- EPHA4 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs147566564, COSV99916352; called by muse, mutect2, varscan2
- EPHA5 | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556854839, COSV56670233; called by muse, mutect2, varscan2
- EPHA6 | c.2051G>T p.R684I (on ENST00000389672 / NM_001080448.3; = p.R76I on NM_173655.4) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV67558233, COSV67575787; called by muse, mutect2, varscan2
- EPHB2 | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1406555949; called by muse, mutect2, varscan2
- EPHB4 | c.2846G>A p.R949Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs373446670; called by mutect2, varscan2
- EPM2AIP1 | c.1412T>G p.F471C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51617698; called by muse, mutect2, varscan2
- EPPK1 | c.6291C>G p.D2097E | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782773843, COSV101599946; called by muse, mutect2
- ERCC4 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.53); catalogued as rs368830992; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERCC6 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs768589918, COSV63388430; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERCC6L | c.3275C>A p.S1092Y | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57822193; called by muse, mutect2, varscan2
- ERCC6L2 | c.1307C>A p.S436Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV56631672; called by muse, mutect2, varscan2
- ERI1 | c.562A>G p.S188G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1312417440; called by muse, mutect2, varscan2
- ERMP1 | c.1835G>T p.R612I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53040025; called by muse, mutect2, varscan2
- ERMP1 | c.1535G>T p.R512I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs374389047; called by mutect2, varscan2
- ERMP1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs774713963; called by muse, mutect2, varscan2
- ESCO1 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200657231, COSV52517980; called by muse, mutect2
- ESRRG | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as rs1175042812, COSV63161834; called by muse, mutect2, varscan2
- ETAA1 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs756846423; called by muse, mutect2, varscan2
- EVC2 | c.3746T>A p.I1249N | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as COSV100185000; called by muse, mutect2, varscan2
- EXOC1 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs1403315395; called by muse, mutect2, varscan2
- EXOC6B | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV55548034; called by muse, mutect2, varscan2
- EXPH5 | c.5235C>A p.F1745L | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as rs746382317, COSV56203867; called by muse, mutect2, varscan2
- EYS | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV60984695; called by muse, mutect2
- EZH2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV57448246; called by muse, mutect2, varscan2
- FAF2 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758524390; called by muse, mutect2, varscan2
- FAM107B | c.106G>A p.E36K (on ENST00000378458 / NM_001320737.1; = p.E211K on NM_031453.3) | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV51692462; called by muse, mutect2, varscan2
- FAM107B | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as rs111681891, COSV51678969, COSV99474231; called by muse, mutect2, varscan2
- FAM107B | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 74/225 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs951701917; called by muse, mutect2, varscan2
- FAM135A | c.1211C>A p.S404* (on ENST00000370479 / NM_001351599.1; = p.S387* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV52047368; called by muse, mutect2, varscan2
- FAM135A | c.4000C>T p.R1334C (on ENST00000370479 / NM_001351599.1; = p.R1121C on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755609488, COSV52049172; called by muse, mutect2, varscan2
- FAM135B | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs758410872, COSV52731787, COSV52738227, COSV99426198; called by muse, mutect2, varscan2
- FAM160A2 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56412891; called by muse, mutect2, varscan2
- FAM221A | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV61387680; called by muse, mutect2, varscan2
- FAM3B | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63613544; called by muse, mutect2, varscan2
- FAM3D | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.036); catalogued as rs765250738; called by muse, mutect2, varscan2
- FAM47A | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs757355904; called by muse, mutect2, varscan2
- FAM83B | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV100173983; called by muse, mutect2, varscan2
- FAM83H | c.3398A>G p.Y1133C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs370499410; called by muse, mutect2, varscan2
- FAM98B | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV104399738; called by muse, mutect2, varscan2
- FAN1 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100756029; called by muse, mutect2, varscan2
- FAN1 | c.1826C>T p.T609M | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs967295940, COSV62952425; called by muse, mutect2, varscan2
- FAP | c.485T>C p.L162S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51867865; called by muse, mutect2, varscan2
- FAR1 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.764); catalogued as COSV100701532, COSV61386995; called by muse, mutect2, varscan2
- FAT1 | c.8728G>A p.D2910N | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753412687, COSV71673025; called by muse, mutect2, varscan2
- FAT1 | c.5383C>T p.R1795* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs769432838, COSV71674862; called by muse, mutect2, varscan2
- FAT4 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.226); catalogued as rs370892297; called by muse, mutect2, varscan2
- FAT4 | c.6607C>T p.R2203W | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs374328795, COSV58685192; called by muse, mutect2, varscan2
- FAT4 | c.8059C>T p.R2687* | Nonsense Mutation (SNP) | VAF 57/136 reads (42%) | catalogued as COSV58711961; called by muse, mutect2, varscan2
- FAT4 | c.8618G>A p.R2873K | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV58704260; called by muse, mutect2, varscan2
- FAT4 | c.9406G>T p.E3136* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV104405896; called by muse, mutect2, varscan2
- FAT4 | c.13497G>T p.E4499D | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV58711435; called by muse, mutect2, varscan2
- FAXDC2 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV58171777; called by muse, mutect2, varscan2
- FBH1 | c.8G>A p.R3Q (on ENST00000362091 / NM_178150.3; = p.R54Q on NM_032807.4) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs184687585, COSV100758650; called by muse, mutect2, varscan2
- FBXL16 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV60965752; called by muse, mutect2, varscan2
- FBXO3 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.348); catalogued as rs1300546629; called by muse, mutect2, varscan2
- FBXO7 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.33); catalogued as rs759130580; called by muse, mutect2, varscan2
- FBXW11 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs1395559753, COSV99439669; called by muse, mutect2, varscan2
- FCRL3 | c.1756G>A p.V586I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs145354138; called by muse, mutect2, varscan2
- FEM1B | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.134); catalogued as rs775266107, COSV60988027; called by muse, mutect2, varscan2
- FER1L6 | c.4192C>T p.P1398S | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.81); PolyPhen probably damaging (1); catalogued as COSV67548635; called by muse, mutect2, varscan2
- FGD4 | c.1406C>T p.T469I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV56780100; called by muse, mutect2, varscan2
- FGF14 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101084423, COSV65941304; called by muse, mutect2, varscan2
- FHL2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs777214115, COSV59080549; called by muse, mutect2, varscan2
- FILIP1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs776455963, COSV52725973; called by muse, mutect2, varscan2
- FKRP | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748272589; called by muse, mutect2, varscan2
- FLACC1 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as rs149980324, COSV51855141; called by muse, varscan2
- FLT3 | c.1943-1G>T p.X648_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV54067540; called by muse, mutect2, varscan2
- FNDC11 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs143315774; called by muse, mutect2, varscan2
- FNDC3B | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs780399563, COSV100395150; called by muse, mutect2, varscan2
- FNDC4 | c.448A>C p.S150R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV99253938; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs777464554; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100435045; called by muse, mutect2, varscan2
- FPR3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs779906302; called by muse, mutect2, varscan2
- FRA10AC1 | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63271346; called by muse, mutect2, varscan2
- FREM1 | c.5734C>T p.R1912W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs747877946, COSV66529835; called by muse, mutect2, varscan2
- FREM2 | c.3131G>A p.R1044K | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV54828291, COSV99749187; called by muse, mutect2
- FREM2 | c.4105A>C p.N1369H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV54836632; called by muse, mutect2, varscan2
- FRMD1 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV51963872; called by muse, mutect2, varscan2
- FSCB | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV61218564; called by muse, mutect2, varscan2
- FSCB | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 49/157 reads (31%) | catalogued as rs919384215, COSV100469532; called by muse, mutect2, varscan2
- FSCN3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50000133; called by muse, mutect2, varscan2
- FSHR | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs267599404, COSV58623080, COSV58625913; called by muse, mutect2
- GABBR1 | c.1746G>T p.K582N | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV63544219; called by muse, mutect2, varscan2
- GABBR2 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.973); catalogued as COSV99410658; called by muse, mutect2, varscan2
- GABRA4 | c.15G>T p.K5N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51928880; called by muse, mutect2, varscan2
- GABRB2 | c.1408C>T p.R470C (on ENST00000274547; = p.R432C on NM_000813.3) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774391847, COSV50905801; called by muse, mutect2, varscan2
- GABRB2 | c.1179C>A p.F393L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV50926511, COSV50951184; called by muse, mutect2, varscan2
- GABRG2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV62716543; called by muse, mutect2, varscan2
- GAD1 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.59); catalogued as rs776783455; called by muse, mutect2, varscan2
- GALC | c.1694A>G p.D565G | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340293257; called by muse, mutect2, varscan2
- GALNT12 | c.410G>T p.R137M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100899132; called by muse, mutect2, varscan2
- GALNT17 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1563076403, COSV61145704; called by muse, varscan2
- GALNT5 | c.1678C>A p.L560I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.291); catalogued as COSV52038716, COSV99375056; called by muse, mutect2, varscan2
- GALNT9 | c.1262C>T p.S421L (on ENST00000328957 / NM_001122636.2; = p.S55L on NM_021808.3) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs973367073, COSV61102749; called by muse, mutect2, varscan2
- GAS2 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1303422974, COSV53410029; called by muse, mutect2, varscan2
- GATA4 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs781198110, COSV58734459, COSV58735180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA5 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs782625539, COSV53346108; called by muse, mutect2, varscan2
- GBF1 | c.3538C>T p.R1180* (on ENST00000369983 / NM_001377137.1; = p.R1179* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as rs372057718, COSV64143662; called by muse, mutect2, varscan2
- GBP1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs750208719, COSV65084564; called by muse, mutect2, varscan2
- GCKR | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as COSV53108746; called by muse, mutect2, varscan2
- GCNA | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as COSV65466583, COSV65468137; called by muse, mutect2, varscan2
- GCNA | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101031729; called by muse, mutect2, varscan2
- GCNA | c.1953G>A p.T651= | Splice Region (SNP) | VAF 14/29 reads (48%) | catalogued as COSV65461844; called by muse, mutect2, varscan2
- GCSAML | c.83G>T p.R28I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100826030; called by muse, mutect2, varscan2
- GDF11 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 21/228 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs1204225512; called by muse, mutect2
- GDF9 | c.709T>G p.F237V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV99737407; called by muse, mutect2, varscan2
- GFRA1 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs757403878, COSV62603885, COSV99051741; called by muse, mutect2
- GID4 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52009546; called by muse, mutect2, varscan2
- GIMAP7 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as rs764216565; called by muse, mutect2, varscan2
- GIMAP8 | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1441723834, COSV56230466, COSV56231402; called by muse, mutect2, varscan2
- GJC1 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV57910727; called by muse, mutect2
- GLI2 | c.2362C>T p.R788C (on ENST00000361492 / NM_001374353.1; = p.R805C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748046557; called by muse, varscan2
- GLIS3 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs753764072, COSV60937461; called by muse, mutect2, varscan2
- GLMN | c.863C>A p.S288Y | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV104427701; called by muse, mutect2, varscan2
- GLOD4 | c.829C>T p.R277* (on ENST00000301328 / NM_001366247.1; = p.R262* on NM_016080.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as rs184466050, COSV56754712; called by muse, mutect2, varscan2
- GLRA1 | c.1116C>A p.F372L (on ENST00000455880 / NM_001146040.2; = p.F364L on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.152); catalogued as COSV51007308, COSV99199475; called by muse, mutect2, varscan2
- GLYAT | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs780192904, COSV53539178, COSV99557646; called by muse, mutect2, varscan2
- GNAS | c.331T>G p.L111V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1252068184; called by muse, varscan2
- GNAT2 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); catalogued as COSV63554675; called by muse, mutect2, varscan2
- GNL2 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs771453763, COSV56170610; called by muse, mutect2, varscan2
- GNLY | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs370130578; called by muse, mutect2, varscan2
- GNPTAB | c.3166A>C p.N1056H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749759865; called by muse, mutect2, varscan2
- GOLGA4 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57887428; called by muse, mutect2, varscan2
- GOLGA4 | c.2504G>T p.R835I | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs760093852, COSV62709475; called by muse, mutect2, varscan2
- GOLGA4 | c.4681G>T p.E1561* | Nonsense Mutation (SNP) | VAF 39/106 reads (37%) | catalogued as COSV62709123, COSV62711691; called by muse, mutect2, varscan2
- GOLGB1 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs773927421; called by muse, mutect2, varscan2
- GPCPD1 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV66830200; called by muse, mutect2, varscan2
- GPR132 | c.993G>T p.M331I | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV61678392; called by muse, mutect2, varscan2
- GPR149 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs375798320; called by muse, mutect2, varscan2
- GPR153 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs748307525; called by muse, mutect2, varscan2
- GPR158 | c.3085G>A p.V1029I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs770315576; called by muse, varscan2
- GPR32 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54514383; called by muse, mutect2, varscan2
- GPR37 | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100390759; called by muse, mutect2, varscan2
- GPR39 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575186714, COSV100257760, COSV61415755; called by muse, mutect2, varscan2
- GPR63 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779044517; called by muse, mutect2, varscan2
- GPRASP1 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs753504960; called by muse, mutect2, varscan2
- GPRASP2 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as rs1221334883; called by muse, mutect2, varscan2
- GPX6 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs761502681; called by muse, mutect2, varscan2
- GRAMD1C | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs550686355, COSV100822803; called by muse, mutect2, varscan2
- GRHL1 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100257897, COSV61407674; called by muse, mutect2, varscan2
- GRIA3 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM074897, COSV99992248; called by mutect2, varscan2
- GRID2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV56174151, COSV56263047; called by muse, mutect2, varscan2
- GRIN2A | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.206); catalogued as COSV58030512; called by muse, mutect2, varscan2
- GRIPAP1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs782030477, COSV64551455, COSV64553616; called by muse, mutect2, varscan2
- GRM1 | c.2869G>A p.V957I | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.191); catalogued as rs1011306026, COSV51221668, COSV51269678; called by muse, mutect2
- GRM4 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs539899143; called by muse, mutect2, varscan2
- GRM6 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV51436137; called by muse, mutect2, varscan2
- GRM7 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63140312; called by muse, mutect2, varscan2
- GRPEL2 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs867201109, COSV61387734; called by muse, mutect2, varscan2
- GRPR | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1246452682, COSV100977625; called by muse, mutect2, varscan2
- GSE1 | c.2383T>C p.F795L | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV53675151; called by muse, mutect2, varscan2
- GSX2 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | catalogued as COSV100482542, COSV100482629; called by muse, mutect2, varscan2
- GTF2E1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs939906050, COSV52205343; called by muse, mutect2, varscan2
- GTF3C2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53126663; called by muse, mutect2, varscan2
- GULP1 | c.785T>G p.F262C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367867124; called by muse, mutect2, varscan2
- GZMB | c.368C>A p.A123D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV53542882; called by muse, mutect2, varscan2
- H2BC17 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.087); catalogued as rs1443292983, COSV58153402; called by muse, mutect2
- HABP2 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV63636926; called by muse, mutect2, varscan2
- HAS2 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1176445398, COSV58264462, COSV58265851; called by muse, mutect2, varscan2
- HCCS | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs771245449; called by muse, mutect2, varscan2
- HCFC1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.304); catalogued as COSV60073046; called by muse, mutect2, varscan2
- HCFC2 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV57558155; called by muse, mutect2, varscan2
- HCRTR2 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs772323802; called by muse, mutect2, varscan2
- HCRTR2 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV63799587; called by muse, mutect2, varscan2
- HEATR1 | c.3766C>A p.L1256I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63980341, COSV63980431; called by muse, mutect2, varscan2
- HEATR5B | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51855095; called by muse, mutect2, varscan2
- HEATR5B | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51852969; called by muse, mutect2, varscan2
- HEATR6 | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs768489630, COSV51747446; called by muse, mutect2, varscan2
- HEATR6 | c.1474C>A p.L492I | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs968372662; called by muse, varscan2
- HEATR6 | c.221A>G p.D74G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs750915401; called by muse, mutect2, varscan2
- HECTD1 | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV67946300; called by muse, mutect2, varscan2
- HEPACAM | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as rs373992036; called by muse, mutect2, varscan2
- HEXD | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100028031; called by muse, mutect2, varscan2
- HIVEP2 | c.5936G>A p.R1979Q | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746928726, COSV50013913; called by muse, mutect2, varscan2
- HLTF | c.2664G>T p.K888N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as rs746821765, COSV59500493; called by muse, mutect2, varscan2
- HOMER1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs757029273; called by muse, mutect2
- HOXD13 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101184090; called by muse, mutect2, varscan2
- HTR4 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.114); catalogued as rs1424493380, COSV58794210; called by muse, mutect2, varscan2
- HUWE1 | c.10472C>A p.S3491Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV99471151; called by muse, mutect2, varscan2
- ICA1L | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV64173605; called by muse, mutect2, varscan2
- ICE2 | c.1702C>A p.L568I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV55030379; called by muse, mutect2, varscan2
- IDH2 | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV57483392; called by muse, mutect2, varscan2
- IFIT1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1026540868; called by muse, mutect2, varscan2
- IFIT2 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV51078660; called by muse, mutect2, varscan2
- IFNA2 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV66505307; called by muse, varscan2
- IFNL3 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV69830160; called by muse, mutect2, varscan2
- IFT172 | c.1199A>C p.K400T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV53135838; called by muse, mutect2, varscan2
- IGHV3-72 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.089); catalogued as COSV101455368, COSV70409497; called by muse, mutect2, varscan2
- IGLV3-22 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as rs374444373; called by muse, mutect2, varscan2
- IGSF1 | c.1811C>T p.P604L | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63836020; called by muse, mutect2, varscan2
- IGSF10 | c.4842G>T p.K1614N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1256066898; called by muse, mutect2, varscan2
- IGSF5 | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV66029695; called by muse, mutect2, varscan2
- IKBKB | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as rs200841053, COSV60598588; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL13RA1 | c.112T>G p.L38V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV65426858; called by muse, mutect2, varscan2
- IL1RAP | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs773448408, COSV50765553; called by muse, mutect2, varscan2
- IL21 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV52645397; called by muse, mutect2, varscan2
- IL36B | c.29A>C p.K10T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.089); catalogued as rs757282283; called by muse, mutect2, varscan2
- ILF3 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV51554858; called by muse, mutect2, varscan2
- ILKAP | c.485T>G p.F162C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54520266; called by muse, mutect2, varscan2
- IMPG2 | c.3640C>A p.Q1214K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1177668593, COSV99514975; called by muse, mutect2, varscan2
- INTS10 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs754588177, COSV67604519; called by muse, mutect2, varscan2
- INTS11 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV60090642; called by muse, mutect2, varscan2
- INTS6L | c.2400C>A p.F800L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV100878283; called by muse, mutect2, varscan2
- INTS8 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV58249728; called by muse, mutect2, varscan2
- INTS8 | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs761505491; called by muse, mutect2, varscan2
- IPCEF1 | c.1275G>T p.K425N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs772792412, COSV54550489; called by mutect2, varscan2
- IQGAP2 | c.1072-1G>T p.X358_splice | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV57180158; called by muse, mutect2, varscan2
- ISG20 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV60143209; called by muse, mutect2, varscan2
- ISM1 | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99078642; called by muse, mutect2, varscan2
- ITCH | c.2452G>T p.E818* (on ENST00000262650 / NM_001257137.3; = p.E777* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs1569001040, COSV52929787; called by muse, mutect2, varscan2
- ITGA7 | c.1891C>T p.R631W (on ENST00000555728; = p.R587W on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs139024853; called by muse, varscan2
- ITGAM | c.3089G>T p.R1030I (on ENST00000648685 / NM_001145808.2; = p.R1029I on NM_000632.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs750934080, COSV54933779; called by muse, mutect2, varscan2
- ITIH2 | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100623424; called by muse, mutect2, varscan2
- ITIH6 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.608); catalogued as rs758361448, COSV54489981; called by muse, mutect2, varscan2
- ITK | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs757740059, COSV70060451; called by muse, mutect2, varscan2
- ITPR2 | c.3127G>T p.E1043* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV101189931, COSV101190335; called by muse, mutect2, varscan2
- ITPRID1 | c.2866A>C p.N956H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs868760875; called by muse, mutect2
- IVNS1ABP | c.208A>C p.I70L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV62250118; called by muse, mutect2, varscan2
- JAK2 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV101081685; called by muse, mutect2, varscan2
- JPH4 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs753148734, COSV58109983; called by muse, mutect2, varscan2
- KANK4 | c.1148G>T p.R383I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100587440; called by muse, mutect2, varscan2
- KANSL1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1258391982, COSV52264523; called by muse, mutect2, varscan2
- KBTBD3 | c.1375C>A p.L459I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as COSV101595663; called by muse, mutect2, varscan2
- KBTBD6 | c.123G>T p.K41N | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV65271302; called by muse, mutect2, varscan2
- KBTBD7 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748813079; called by muse, mutect2, varscan2
- KCMF1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV69053190, COSV69053501; called by muse, mutect2, varscan2
- KCNA10 | c.1090C>A p.L364I | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV104424807; called by muse, mutect2, varscan2
- KCNA3 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901988; called by muse, mutect2, varscan2
- KCNB1 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs755481445, COSV100870504; called by muse, mutect2, varscan2
- KCNC2 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as rs200951837, COSV54367018; called by mutect2, varscan2
- KCNH7 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1323322666; called by muse, mutect2
- KCNK15 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as COSV65719376, COSV65719548; called by muse, mutect2, varscan2
- KCNK6 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs558034240; called by muse, mutect2, varscan2
- KCNS2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54641246; called by muse, mutect2, varscan2
- KCNT1 | c.981C>T p.F327= (on ENST00000488444; = p.F346= on NM_020822.3) | Splice Region (SNP) | VAF 10/27 reads (37%) | catalogued as rs767434859, COSV53697124; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNU1 | c.801T>G p.I267M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.068); catalogued as COSV67758031; called by muse, mutect2, varscan2
- KCTD4 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61241271; called by muse, mutect2, varscan2
- KDM4D | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.044); catalogued as COSV100624345; called by muse, mutect2, varscan2
- KDM5B | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1277190443; called by muse, mutect2, varscan2
- KEL | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1230602052; called by muse, mutect2, varscan2
- KHK | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs104893644, CM940997; ClinVar: affects; called by muse, mutect2, varscan2
- KIAA0232 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as CM124417, COSV56929835; called by muse, mutect2, varscan2
- KIAA1217 | c.3098C>T p.S1033L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs534553518, COSV56821317; called by muse, mutect2, varscan2
- KIAA1522 | c.2871G>T p.K957N (on ENST00000373480 / NM_001198972.2; = p.K1016N on NM_020888.3) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.32); catalogued as rs1238517439; called by muse, mutect2, varscan2
- KIAA1841 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54376216; called by muse, mutect2, varscan2
- KIF1A | c.4394G>A p.R1465H (on ENST00000320389 / NM_001379639.1; = p.R1457H on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV57493789, COSV57494300; called by muse, mutect2, varscan2
- KIF20B | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201280490, COSV53317475; called by muse, mutect2, varscan2
- KIF20B | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770462070, COSV53303511; called by muse, mutect2, varscan2
- KIF20B | c.2302G>T p.E768* (on ENST00000371728 / NM_001284259.2; = p.E728* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV53302149; called by muse, mutect2, varscan2
- KIF20B | c.5126C>A p.S1709Y (on ENST00000371728 / NM_001284259.2; = p.S1669Y on NM_016195.4) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1031277703; called by muse, mutect2, varscan2
- KIF23 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs1191107083; called by muse, mutect2, varscan2
- KIF3B | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65227279; called by muse, mutect2, varscan2
- KIF5B | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755716349; called by muse, mutect2, varscan2
- KIF5C | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV101276130; called by muse, mutect2, varscan2
- KIRREL1 | c.2243G>A p.R748Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1007075644, COSV63286155; called by muse, mutect2, varscan2
- KIT | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55399133; called by muse, mutect2, varscan2
- KIZ | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55684118, COSV99852402; called by muse, varscan2
- KIZ | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV55685438; called by muse, varscan2
- KLHL23 | c.139A>C p.I47L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV55867986; called by muse, mutect2, varscan2
- KLHL24 | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.093); catalogued as COSV54425222; called by muse, mutect2, varscan2
- KLHL41 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.718); catalogued as rs1027488195; called by muse, mutect2, varscan2
- KMT2C | c.8651G>A p.R2884Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs761131667, COSV51485453; called by muse, mutect2, varscan2
- KMT2C | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV51437634; called by muse, mutect2, varscan2
- KMT2D | c.8924G>A p.R2975H | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs770885860, COSV56499528; ClinVar: uncertain significance; called by mutect2, varscan2
3,574 further variants in this file (2,728 protein-altering or splice-affecting, 752 silent, 94 other) are not listed here.
